Gene-level copy-number profile of tumor specimen ALCH-B73A-TTP1-A from ALCHEMIST case ALCH-B73A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,286 days).
Specimen ALCH-B73A-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8bc1858f-6656-4da7-8529-1d02445265de.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B73A-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/65a12f35-ffba-406d-a1d0-c2fabd934db7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 11,392; copy number 2: 46,137; copy number 3: 1,187; copy number 4: 39; copy number 5: 9.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,394,317–46,516,216, 4 genes: FAAH, FAAHP1, LINC01398, DMBX1.
- chr1:54,980,628–54,992,288, 2 genes: TMEM61, AL590440.1.
- chr3:9,902,612–9,916,402, 1 gene: IL17RE.
- chr3:9,919,051–9,919,153, 1 gene (within-gene range 0–2): RNU6-882P.
- chr3:52,794,768–52,835,729, 5 genes (within-gene range 0–2): ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr4:9,493,736–9,498,066, 1 gene: UNC93B7.
- chr5:659,862–693,352, 2 genes (within-gene range 0–2): TPPP, AC026740.1.
- chr7:73,732,569–73,738,867, 3 genes: RN7SL265P, ABHD11-AS1, ABHD11.
- chr7:128,830,406–128,910,719, 5 genes (within-gene range 0–1): FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr8:143,684,452–143,713,898, 4 genes (within-gene range 0–2): ZNF707, LINC02878, CCDC166, AC105219.2.
- chr9:93,091,460–93,134,251, 3 genes: AL451065.1, CARD19, NINJ1.
- chr9:93,951,627–93,955,355, 1 gene: BARX1.
- chr10:72,274,915–72,355,149, 2 genes (within-gene range 0–1): DDIT4-AS1, DNAJB12.
- chr10:79,068,966–79,316,528, 1 gene: ZMIZ1.
- chr11:67,398,181–67,425,607, 3 genes (within-gene range 0–1): PPP1CA, TBC1D10C, CARNS1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:120,095,099–120,117,502, 1 gene (within-gene range 0–2): RAB35.
- chr14:64,704,102–64,750,249, 1 gene (within-gene range 0–2): PLEKHG3.
- chr14:64,785,626–64,785,686, 1 gene (within-gene range 0–2): MIR7855.
- chr15:25,178,738–25,250,940, 40 genes (within-gene range 0–2): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr16:11,668,455–11,679,152, 1 gene (within-gene range 0–2): SNN.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr17:18,950,345–19,062,669, 7 genes: SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1, SNORD3B-1.
- chr17:19,112,000–19,143,689, 4 genes: AC007952.4, SNORD3D, SNORD3D, AC007952.6.
- chr17:63,909,597–63,932,336, 4 genes: CSHL1, GH1, AC127029.3, CD79B.
- chr19:2,269,525–2,341,172, 6 genes (within-gene range 0–2): AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2, LSM7.
- chr21:43,169,008–43,172,805, 1 gene: CRYAA.
- chr22:18,615,581–18,625,289, 2 genes: Metazoa_SRP, SUSD2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,785,285–1,891,117, 1 gene, copy number 5: GNB1.
- chr17:19,077,775–19,096,837, 4 genes, copy number 5: AC007952.3, KYNUP2, AC007952.7, AC007952.2.
- chr17:75,135,248–75,168,281, 1 gene, copy number 5 (within-gene range 1–5): JPT1.
- chr17:75,165,586–75,182,959, 1 gene, copy number 5: SUMO2.
- chr21:43,107,942–43,168,646, 1 gene, copy number 5 (within-gene range 1–5): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 5: AP001631.1.

Autosomal genes at a single copy (total copy number 1): 8,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
